Somatic mutation profile of tumor specimen 0DUHHU from CCDI case PBCJCF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DUHHU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc56d379-1a7d-43f5-a056-969372a6acca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHG5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81949768-ff26-4d6e-a326-24dd449e5e6a

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITSN2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 174/690 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61951318; called by muse, mutect2, varscan2
- TGFBR3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 252/649 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs957231039, COSV53027400; called by muse, mutect2, varscan2
- MUC13 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 32/720 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, mutect2
- GOLGA8Q | c.1276+96G>A | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as rs879032460, COSV60799867; called by mutect2, varscan2
- RUSC1 | c.-86-215A>G | Intron (SNP) | VAF 168/441 reads (38%) | called by muse, mutect2, varscan2
